Surgical pathology report (de-identified scan), TCGA case TCGA-D7-A6ET, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Greater Poland Cancer Center, specimen TCGA-D7-A6ET-01A (Primary Tumor).

Department of Cancer Pathology

Patient: XXX

Age:

Gender: M

Examination result

Unit in charge:

Physician in charge:

Clinical diagnosis (suspicion) Cancer of the cardia infiltrating the oesophagus

Date of admission:

Material:

1) Material: stomach, Method of collection: Total organ resection

Histopathological diagnosis

Examination performed on:

Stomach adenocarcinoma tubular.

Cancer metastases in lymph nodes NO VII/XXXIV.

G2, pT3, pN3a.

Type intestinal sec.

* codes acc. to ICD-O-3 or SNOMED

Macroscopic description:

Specimen consisting of the stomach, after being incised along the greater curvature, sized 20 x 13.5 cm with the omentum sized 26.5 x 15 cm, no focal lesions found macroscopically.

Tumour in the lesser curvature sized 4 x 3.7 x 1.9 cm.

Distance from the proximal end: 2 cm, from distal end: 7 cm.

Microscopic description:

Adenocarcinoma tubulare G2.

Tumour penetrates the full thickness of the stomach wall and perigastric fat tissue.

Signs of massive vascular invasion.

Surgical incision lines clear of cancer invasion.

The omentum free of neoplastic lesions.

LYMPH NODES:

- 1,2/ (cardia): metastases carcinomatosae in lymphonodo No (/II)

- lesser curvature: metastases carcinomatosae in lymphonodis NO VI/XXII.

Infiltratio carcinomatosae capsulae lymphonodorum et taelae adiposae perinodalis.

- (greater curvature): lymphonodulitis reactiva NO V

Assistant:

Pathologist:

Result of immunohistochemical examination:

Examination performed on:

HER2 protein stained with

HER-2/neu (4B5).HER-2/neu (4B5) Rabbit Monoclonal Antibody

Negative reaction in invasive cancerous cells (Score = 0)

Assistant:

Pathologist: :

CONTACT YOUR DOCTOR WITH THIS REPORT!

Source: NCI Genomic Data Commons file f0f660b9-1638-4c58-b3cd-71927a1e620d (TCGA-D7-A6ET.F6E8B420-DEE1-4AAF-9BE6-F39279050E0B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).